Gene-level copy-number profile of tumor specimen CUPP-B38P-TTM1-A from CCG case CUPP-B38P, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 64.8 years (23,670 days).
Specimen CUPP-B38P-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eafde03e-92c0-4bd0-a2a0-17eb5198ba6b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38P-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/5fe9ef40-3d62-4cb5-a001-086851bf5649

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 113; copy number 1: 2,276; copy number 2: 1,789; copy number 3: 23,333; copy number 4: 19,857; copy number 5: 5,505; copy number 6: 2,772; copy number 7: 2,489; copy number 8: 150; copy number 9: 217; copy number 10: 6; copy number 11: 10; copy number 12: 98; copy number 13: 62; copy number 14: 1; copy number 15: 73; copy number 17: 39; copy number 19: 41; copy number 26: 38.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:20,658,309–23,438,700, 64 genes (within-gene range 0–3) (broad region; genes not listed).
- chr9:27,535,640–29,318,952, 12 genes: C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1.
- chr9:30,388,935–30,575,012, 2 genes: LINC01242, SLC4A1APP1.
- chr9:37,878,116–37,904,353, 3 genes (within-gene range 0–2): PAICSP1, SLC25A51, TMX2P1.
- chr9:37,936,707–38,624,990, 19 genes (within-gene range 0–2): RNU7-124P, U8, AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A.
- chr11:55,602,360–55,607,645, 1 gene: OR4C11.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,224 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:218,043,505–219,958,647, 23 genes, copy number 9: LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710, LYPLAL1-DT, LYPLAL1, RIMKLBP2, AL360093.1, AC096642.1, LYPLAL1-AS1, AL356364.1, ZC3H11B, SLC30A10, RNA5SP76.
- chr2:8,721,081–8,837,630, 1 gene, copy number 9: KIDINS220.
- chr2:24,491,914–24,770,702, 1 gene, copy number 9 (within-gene range 6–9): NCOA1.
- chr2:24,676,309–24,793,382, 2 genes, copy number 9 (within-gene range 6–9): RNU6-936P, PTRHD1.
- chr2:241,315,100–241,354,027, 3 genes, copy number 8 (within-gene range 4–8): SEPTIN2, AC104841.1, AC005104.1.
- chr2:242,087,351–242,088,457, 1 gene, copy number 8: AC093642.2.
- chr3:88,948,142–90,184,733, 8 genes, copy number 8–12: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr3:107,522,936–108,694,840, 15 genes, copy number 7: BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3.
- chr3:129,818,932–129,819,876, 2 genes, copy number 7: RNY3P13, U6.
- chr3:152,243,828–152,496,813, 5 genes, copy number 8: MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:177,010,719–184,712,064, 169 genes, copy number 7–8 (broad region; genes not listed).
- chr3:184,812,143–190,892,429, 105 genes, copy number 7 (broad region; genes not listed).
- chr3:195,274,745–198,123,232, 112 genes, copy number 7 (broad region; genes not listed).
- chr5:6,532,891–45,895,970, 558 genes, copy number 7 (broad region; genes not listed).
- chr7:38,269,491–38,300,322, 6 genes, copy number 9 (within-gene range 4–9): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:74,650,231–74,851,551, 5 genes, copy number 7–14: GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2.
- chr7:88,219,359–101,058,859, 292 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:102,748,971–106,838,480, 68 genes, copy number 7 (broad region; genes not listed).
- chr7:114,086,327–128,092,609, 173 genes, copy number 7–19 (within-gene range 5–19) (broad region; genes not listed).
- chr7:128,297,685–128,822,132, 36 genes, copy number 8: RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW, CCDC136.
- chr7:129,028,889–134,350,791, 105 genes, copy number 12–17 (broad region; genes not listed).
- chr7:136,262,558–138,703,062, 37 genes, copy number 26: AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1, DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2.
- chr7:142,487,863–142,667,718, 25 genes, copy number 9: TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6.
- chr8:57,341,021–134,390,487, 1,085 genes, copy number 7–11 (within-gene range 7–12) (broad region; genes not listed).
- chr8:140,657,900–141,002,216, 4 genes, copy number 9: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr11:68,460,731–68,616,711, 3 genes, copy number 7: PPP6R3, NDUFA3P2, AP003096.1.
- chr11:86,955,616–91,234,388, 105 genes, copy number 9 (broad region; genes not listed).
- chr11:92,336,032–92,336,496, 1 gene, copy number 11: NDUFB11P1.
- chr11:99,020,949–100,358,885, 1 gene, copy number 12 (within-gene range 3–12): CNTN5.
- chr11:100,336,856–105,982,092, 87 genes, copy number 12–15 (broad region; genes not listed).
- chr11:120,325,296–120,333,686, 1 gene, copy number 7: TLCD5.
- chr14:21,918,188–22,492,907, 66 genes, copy number 9–12 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.
- chr16:32,475,051–32,478,250, 1 gene, copy number 15: ABCD1P3.
- chr16:57,152,466–57,253,635, 6 genes, copy number 10 (within-gene range 5–10): PSME3IP1, AC009090.6, RSPRY1, ARL2BP, AC009090.3, AC009090.1.
- chr16:61,647,242–62,037,035, 1 gene, copy number 8 (within-gene range 5–8): CDH8.
- chr16:61,743,154–61,940,697, 2 genes, copy number 8: RN7SKP76, AC012174.1.
- chr16:88,638,572–88,640,468, 1 gene, copy number 8: IL17C.
- chr17:59,618,553–59,707,626, 3 genes, copy number 7 (within-gene range 4–7): AC091271.1, CLTC, PTRH2.
- chr19:34,593,329–35,908,295, 102 genes, copy number 8–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
